Somatic mutation profile of tumor specimen TCGA-AG-3881-01A (aliquot TCGA-AG-3881-01A-01W-0899-10) from TCGA case TCGA-AG-3881, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Unknown primary site; AJCC pathologic stage: Stage IIA; Age at diagnosis: 83.4 years (30,467 days).
Specimen TCGA-AG-3881-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62f4dbc9-8a19-4ea4-a58d-aa4ca7ae4a27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3881-10A (Blood Derived Normal), aliquot TCGA-AG-3881-10A-01W-0901-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ee285e2-f58a-455e-8947-bf99826be14c

The open-access MAF lists 116 somatic variants for this specimen: 84 protein-altering or splice-affecting, 30 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 30, Frame Shift Del 3, Nonsense Mutation 3, Splice Site 3, RNA 2, Splice Region 1, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4099C>T p.Q1367* | Nonsense Mutation (SNP) | VAF 108/198 reads (55%) | hotspot (GDC flag); catalogued as rs121913328, CM940072, COSV57323776, COSV57337799; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 133/375 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GRIN2B | c.99dup p.S34Qfs*25 | Frame Shift Ins (INS) | VAF 18/124 reads (15%) | catalogued as rs398122823; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 262/398 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- KRAS | c.181C>G p.Q61E | Missense Mutation (SNP) | VAF 259/394 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as rs121913238, COSV55502066, COSV55502677; ClinVar: likely pathogenic; called by muse, mutect2
- ACAD9 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as rs377547811; called by muse, mutect2, varscan2
- ADGRV1 | c.12485T>C p.I4162T | Missense Mutation (SNP) | VAF 173/257 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs370746571; called by muse, mutect2, varscan2
- AKR1B15 | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 54/336 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.273); catalogued as rs781519182, COSV71151420; called by muse, mutect2, varscan2
- ALS2CL | c.2606C>T p.S869L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as rs766145175, COSV59673915; called by muse, mutect2, varscan2
- ARMH4 | c.1813G>A p.D605N | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.22); catalogued as COSV50762925; called by muse, mutect2, varscan2
- ATP5MG | c.253A>T p.M85L | Missense Mutation (SNP) | VAF 170/450 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.2); catalogued as COSV100329261; called by mutect2, varscan2
- C12orf42 | c.1031C>T p.T344M | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as rs779166148, COSV59381064; called by muse, mutect2, varscan2
- C7 | c.2519C>T p.A840V | Missense Mutation (SNP) | VAF 115/146 reads (79%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs761687811, COSV57472699; called by muse, mutect2, varscan2
- CACNA1I | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs770899366, COSV60814489; called by muse, mutect2, varscan2
- CCDC117 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.11); catalogued as rs762850742, COSV50770696; called by muse, mutect2, varscan2
- CCDC159 | c.110A>T p.E37V | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100712288; called by muse, mutect2, varscan2
- CCDC159 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs768283234, COSV99264534; called by muse, mutect2, varscan2
- CDCA3 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV99976979; called by muse, mutect2, varscan2
- CENPB | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as COSV60145414; called by mutect2, varscan2
- CERS5 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.017); catalogued as COSV100452018; called by muse, mutect2
- CHKA | c.1202T>G p.I401R | Missense Mutation (SNP) | VAF 92/202 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV55839212; called by muse, mutect2, varscan2
- CNN1 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.413); catalogued as rs745990452, COSV52947530, COSV52947556; called by muse, mutect2, varscan2
- CRAMP1 | c.3125C>T p.S1042F | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.367); catalogued as COSV99246103; called by muse, mutect2, varscan2
- CTNNB1 | c.1549C>T p.L517F | Missense Mutation (SNP) | VAF 192/602 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV62695497; called by muse, mutect2, varscan2
- CUBN | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 74/231 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs145380076, COSV64724721; called by muse, mutect2, varscan2
- DAAM2 | c.1492C>T p.R498C | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs375733561; called by muse, mutect2, varscan2
- DPY19L1 | c.1034G>A p.C345Y | Missense Mutation (SNP) | VAF 50/215 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.291); catalogued as COSV60581597; called by muse, mutect2, varscan2
- DYRK3 | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as rs200229954, COSV65605724; called by muse, mutect2, varscan2
- EIF3D | c.1282A>G p.N428D | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53403112; called by muse, mutect2, varscan2
- FAM83B | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 35/139 reads (25%) | catalogued as rs761383368, COSV60920745; called by muse, mutect2, varscan2
- FMN2 | c.4330A>G p.I1444V | Missense Mutation (SNP) | VAF 286/1417 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV60425059; called by muse, mutect2, varscan2
- FRYL | c.4931G>A p.R1644H | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as rs372020475; called by muse, mutect2, varscan2
- FSTL1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs554312023, COSV99820760; called by muse, mutect2, varscan2
- GPR174 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 135/584 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.149); catalogued as COSV52131908; called by muse, mutect2, varscan2
- GRM5 | c.1747G>C p.A583P | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV59598474; called by muse, mutect2, varscan2
- H2AC20 | c.299_300del p.K100Sfs*11 | Frame Shift Del (DEL) | VAF 10/77 reads (13%) | catalogued as rs782028961; called by pindel, varscan2
- HCCS | c.253A>G p.M85V | Missense Mutation (SNP) | VAF 64/328 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs752050558, COSV100335748; called by mutect2, varscan2
- HCCS | c.751T>A p.S251T | Missense Mutation (SNP) | VAF 126/391 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV100335750; called by muse, mutect2, varscan2
- KIF2C | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.774); catalogued as rs200680875, COSV64763904; called by muse, mutect2
- KLHL20 | c.680G>A p.S227N | Missense Mutation (SNP) | VAF 187/316 reads (59%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as COSV52941091; called by muse, mutect2, varscan2
- KMT2C | c.7443-1G>C p.X2481_splice | Splice Site (SNP) | VAF 16/56 reads (29%) | catalogued as COSV51333129, COSV51430440, COSV51435943; called by mutect2, varscan2
- LRRIQ3 | c.1248A>T p.K416N | Missense Mutation (SNP) | VAF 407/1304 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.052); catalogued as COSV63050503; called by muse, mutect2, varscan2
- MAP4 | c.653T>G p.V218G | Missense Mutation (SNP) | VAF 29/408 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV100805934; called by muse, mutect2
- METTL7A | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 54/261 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs749947319, COSV59840564, COSV59841223; called by muse, mutect2, varscan2
- MINAR1 | c.1485G>T p.Q495H | Missense Mutation (SNP) | VAF 41/65 reads (63%) | SIFT tolerated, low confidence (0.43); PolyPhen possibly damaging (0.459); catalogued as COSV59581619; called by muse, mutect2, varscan2
- MTBP | c.376T>G p.C126G | Missense Mutation (SNP) | VAF 262/1543 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.426); catalogued as COSV59961678; called by muse, mutect2, varscan2
- MYH3 | c.3436G>T p.E1146* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV99878377; called by muse, mutect2, varscan2
- NCAPD3 | c.2335G>C p.D779H | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV101599369; called by muse, mutect2, varscan2
- NELL2 | c.2400+1G>T p.X800_splice | Splice Site (SNP) | VAF 43/166 reads (26%) | catalogued as COSV100419892; called by muse, mutect2, varscan2
- NOTCH3 | c.3425C>A p.A1142D | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as COSV99657680; called by muse, mutect2, varscan2
- NUP155 | c.3151A>C p.K1051Q (on ENST00000231498 / NM_153485.3; = p.K992Q on NM_004298.4) | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.536); catalogued as COSV51528478; called by muse, mutect2, varscan2
- OBSCN | c.11491G>A p.V3831M | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776221063, COSV99480312; called by muse, mutect2, varscan2
- OR10G4 | c.836C>T p.T279M | Missense Mutation (SNP) | VAF 69/208 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs201358968; called by muse, mutect2, varscan2
- OR13C8 | c.926A>G p.N309S | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1474651757, COSV100622992; called by muse, mutect2
- PDE10A | c.1452C>A p.N484K | Missense Mutation (SNP) | VAF 190/504 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV100605217; called by muse, mutect2, varscan2
- PLEKHA4 | c.94C>T p.R32W | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201547716, COSV54361279; called by muse, mutect2, varscan2
- POLR1B | c.3322G>A p.D1108N | Missense Mutation (SNP) | VAF 93/277 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.345); catalogued as rs773808006, COSV54496548; called by muse, mutect2, varscan2
- POU4F2 | c.244G>T p.G82W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV55583587; called by mutect2, varscan2
- PTPRD | c.3415G>T p.G1139C | Missense Mutation (SNP) | VAF 714/1395 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as COSV61936429; called by muse, mutect2, varscan2
- RAB6B | c.72C>T p.V24= | Splice Region (SNP) | VAF 63/229 reads (28%) | catalogued as rs373466732, COSV99557915; called by muse, mutect2, varscan2
- RB1 | c.2083A>G p.M695V | Missense Mutation (SNP) | VAF 111/401 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV57301511; called by muse, mutect2, varscan2
- RHD | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 89/122 reads (73%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1053352; called by muse, mutect2, varscan2
- SAMD9L | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 225/851 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); catalogued as COSV100560834; called by muse, mutect2, varscan2
- SCN4A | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs150158100, COSV101438531; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SEPTIN4 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 92/161 reads (57%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); catalogued as rs1041599764, COSV58727478, COSV58729300; called by muse, mutect2, varscan2
- SPEF1 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs779165045, COSV101124224; called by muse, mutect2
- SPTA1 | c.5905A>G p.K1969E | Missense Mutation (SNP) | VAF 86/577 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100935122; called by muse, mutect2, varscan2
- SSC4D | c.1553A>T p.Q518L | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.75); PolyPhen benign (0.139); catalogued as COSV51881830; called by muse, mutect2, varscan2
- STK36 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs751003140, COSV99831564; called by muse, mutect2, varscan2
- STXBP1 | c.1663G>C p.E555Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV64812586; called by muse, varscan2
- TENM1 | c.7645C>T p.R2549W | Missense Mutation (SNP) | VAF 109/184 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs755183073, COSV100950306, COSV64430859; called by muse, mutect2, varscan2
- TENT4A | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 75/89 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1380626286, COSV50094625; called by muse, mutect2, varscan2
- TNFAIP3 | c.2296G>A p.A766T | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.968); catalogued as rs5029957, COSV52799372, COSV52801258; called by muse, varscan2
- TRAPPC11 | c.347A>C p.E116A | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV100591893; called by muse, mutect2, varscan2
- TRAPPC9 | c.2135C>A p.P712H | Missense Mutation (SNP) | VAF 121/592 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV101227748; called by muse, mutect2, varscan2
- TRPS1 | c.3G>T p.M1? (on ENST00000220888 / NM_001330599.2; = p.M14I on NM_014112.5 and 1 other RefSeq transcript) | Translation Start Site (SNP) | VAF 63/166 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); catalogued as COSV55253529, COSV99631795; called by muse, mutect2, varscan2
- TSHZ3 | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 73/177 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as COSV53666080; called by muse, varscan2
- UGT2A3 | c.631A>G p.N211D | Missense Mutation (SNP) | VAF 66/191 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52361169, COSV99279932; called by muse, mutect2, varscan2
- YME1L1 | c.602-2A>C p.X201_splice (on ENST00000326799 / NM_139312.3; = p.X144_splice on NM_014263.4) | Splice Site (SNP) | VAF 76/328 reads (23%) | catalogued as COSV100463803; called by muse, mutect2, varscan2
- YME1L1 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.216); catalogued as COSV58758649; called by muse, mutect2, varscan2
- ZBED6CL | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs370437244; called by muse, mutect2, varscan2
- ZNF77 | c.1256T>G p.F419C | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100094522; called by muse, varscan2
- DAZL | c.353del p.N118Ifs*41 | Frame Shift Del (DEL) | VAF 94/288 reads (33%) | called by mutect2, pindel, varscan2
- KRT78 | c.1356del p.S453Afs*20 | Frame Shift Del (DEL) | VAF 34/136 reads (25%) | called by mutect2, pindel, varscan2
- ATP10A | c.4377G>T p.T1459= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV63515493; called by muse, mutect2, varscan2
- COL27A1 | c.4620A>T p.A1540= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as COSV61924098; called by muse, mutect2, varscan2
- COL5A1 | c.4521C>A p.G1507= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV65667449; called by muse, varscan2
- CRISP1 | c.132C>T p.I44= | Silent (SNP) | VAF 773/1674 reads (46%) | catalogued as COSV59993170; called by muse, varscan2
- DNAH10 | c.1554G>T p.R518= (on ENST00000409039; = p.R457= on NM_207437.3) | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV68990732; called by muse, mutect2, varscan2
- EPS8 | c.639C>T p.P213= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as COSV55529125; called by muse, mutect2, varscan2
- FAP | c.1149T>C p.T383= | Silent (SNP) | VAF 26/246 reads (11%) | catalogued as COSV51860504; called by muse, mutect2, varscan2
- FCGBP | c.306G>A p.K102= | Silent (SNP) | VAF 19/145 reads (13%) | called by muse, varscan2
- FNBP1L | c.972C>T p.L324= | Silent (SNP) | VAF 57/191 reads (30%) | catalogued as rs778253994, COSV53092437; called by muse, mutect2, varscan2
- IGHG1 | c.255G>C p.V85= | Silent (SNP) | VAF 47/318 reads (15%) | called by muse, mutect2, varscan2
- MEP1B | c.360G>A p.K120= | Silent (SNP) | VAF 128/232 reads (55%) | catalogued as COSV52496530; called by muse, mutect2, varscan2
- NCDN | c.1830G>C p.R610= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV61935107; called by muse, mutect2, varscan2
- OR10H2 | c.207C>T p.S69= | Silent (SNP) | VAF 80/616 reads (13%) | catalogued as rs1448794833, COSV59945703; called by muse, mutect2, varscan2
- PCDHGA8 | c.1050G>A p.T350= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as COSV53921451; called by muse, mutect2, varscan2
- PHLPP2 | c.2700G>A p.T900= | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as rs780474617, COSV100673739; called by muse, mutect2, varscan2
- RDH16 | c.786G>A p.S262= | Silent (SNP) | VAF 40/131 reads (31%) | catalogued as rs372244884; called by muse, mutect2, varscan2
- REXO5 | c.990G>A p.S330= | Silent (SNP) | VAF 34/524 reads (6%) | catalogued as rs766851919, COSV54473563; called by muse, mutect2
- SATB2 | c.1710C>T p.H570= | Silent (SNP) | VAF 29/131 reads (22%) | catalogued as rs764708410, COSV53479858, COSV53481127; called by muse, mutect2, varscan2
- SLC30A8 | c.882C>T p.V294= | Silent (SNP) | VAF 123/617 reads (20%) | catalogued as rs768720476, COSV69969376; called by muse, mutect2, varscan2
- SLC6A15 | c.2034C>T p.H678= | Silent (SNP) | VAF 300/573 reads (52%) | catalogued as rs140619291, COSV57020560; called by muse, mutect2, varscan2
- SLC7A3 | c.1447T>C p.L483= | Silent (SNP) | VAF 78/448 reads (17%) | catalogued as rs780964394, COSV53227015; called by muse, mutect2, varscan2
- SLITRK2 | c.670T>C p.L224= | Silent (SNP) | VAF 18/135 reads (13%) | catalogued as rs781856962, COSV59424143; called by muse, mutect2, varscan2
- SNED1 | c.1599C>T p.T533= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs761318687, COSV60021527; called by muse, varscan2
- SORBS2 | c.1401C>T p.S467= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as rs1303727618, COSV52995492, COSV99509831; called by muse, mutect2, varscan2
- TRIM5 | c.336C>A p.V112= | Silent (SNP) | VAF 24/122 reads (20%) | catalogued as COSV59899194; called by muse, mutect2, varscan2
- TRPC5 | c.300G>A p.L100= | Silent (SNP) | VAF 21/476 reads (4%) | catalogued as COSV99461478; called by muse, mutect2
- UTP6 | c.1035C>T p.F345= | Silent (SNP) | VAF 14/484 reads (3%) | catalogued as COSV99911987; called by muse, mutect2
- VTN | c.759C>T p.N253= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs782405279, COSV56873063, COSV56874739; called by muse, mutect2, varscan2
- ZKSCAN5 | c.528G>A p.Q176= | Silent (SNP) | VAF 16/213 reads (8%) | catalogued as COSV100460248; called by muse, mutect2
- ZNF629 | c.1692G>A p.P564= | Silent (SNP) | VAF 15/23 reads (65%) | catalogued as rs763344745, COSV52697870; called by muse, mutect2, varscan2
- MIR519E | n.25G>A | RNA (SNP) | VAF 133/306 reads (43%) | catalogued as rs1199021002; called by muse, varscan2
- MIR519E | n.26G>A | RNA (SNP) | VAF 127/303 reads (42%) | catalogued as rs1249808405; called by muse, varscan2
